Gene-level copy-number profile of tumor specimen TCGA-FI-A2D2-01A from TCGA case TCGA-FI-A2D2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.4 years (24,260 days).
Specimen TCGA-FI-A2D2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.955a9988-ae3e-4ed4-a05b-b49d94ab35eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2D2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17384888-b2a2-41a4-8776-cea723097d3b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 11,526; copy number 3: 13,927; copy number 4: 29,202; copy number 5: 4,443; copy number 6: 269; copy number 7: 124; copy number 9: 27; copy number 10: 160; copy number 15: 64; copy number 22: 44; copy number 23: 3; copy number 33: 3; copy number 42: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2D2-01A-11D-A17C-01): tumor purity 0.68, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–88,049,823, 6 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 316 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,750,430–9,026,345, 16 genes, copy number 10: RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7.
- chr8:40,298,697–41,650,817, 22 genes, copy number 10: SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3.
- chr8:41,660,441–41,665,566, 3 genes, copy number 10: MIR486-1, MIR486-2, AC113133.1.
- chr9:127,866,486–128,334,072, 27 genes, copy number 9 (within-gene range 4–9): AK1, AL157935.2, MIR4672, ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2, FAM102A, AL360268.2, NAIF1, SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1, LCN2, C9orf16, CIZ1, DNM1, MIR199B, MIR3154, GOLGA2, SWI5, TRUB2, AL359091.3, COQ4.
- chr15:61,239,906–62,844,631, 28 genes, copy number 15–33 (within-gene range 2–33): AC107905.1, AC104574.2, AC104574.1, AC018618.1, AC018618.2, LINC02349, AC009554.1, VPS13C, AC009554.2, AC104590.1, C2CD4A, NPM1P47, C2CD4B, AC126323.2, AC126323.1, AC126323.3, Metazoa_SRP, GOLGA2P11, AC126323.4, AC126323.6, AC126323.5, MIR8067, MIR6085, HMGN1P26, AC032011.1, TLN2, MGC15885, AC100839.1.
- chr17:28,256,375–28,750,956, 57 genes, copy number 15–42: AC061975.2, AC061975.4, AC061975.1, AC061975.5, AC061975.3, KRT18P55, TMEM97, IFT20, TNFAIP1, POLDIP2, TMEM199, AC002094.1, MIR4723, AC002094.2, SEBOX, AC002094.3, SARM1, VTN, AC002094.4, AC002094.5, SLC46A1, AC015917.2, H3P41, AC015917.1, AC005726.1, RPS7P1, SLC13A2, FOXN1, UNC119, PIGS, ALDOC, AC005726.3, SPAG5, SPAG5-AS1, RSKR, AC005726.4, KIAA0100, AC005726.2, SDF2, RPS12P28, SUPT6H, AC010761.3, PROCA1, RAB34, RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5.
- chr20:31,664,452–32,207,743, 23 genes, copy number 10: BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2.
- chr22:20,299,760–22,245,515, 140 genes, copy number 10–22 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
